Gene-level copy-number profile of specimen HCM-CSHL-0853-C56-85G from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85G: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b10d2997-c9ee-4734-a5a2-f7e8ef6560d2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0853-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/a2259ec3-29ce-40f2-b3bb-887758b35a90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 24,363; copy number 2: 28,666; copy number 3: 3,269; copy number 4: 942; copy number 5: 1,092; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,186,694–22,214,672, 46 genes: IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr17:31,094,927–31,713,853, 21 genes (within-gene range 0–1): NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3, AC007923.2, RNU6-1134P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,094 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:192,796,815–193,176,864, 3 genes, copy number 5–6: MB21D2, AC092966.1, VEZF1P1.
- chr6:76,092,834–76,092,940, 1 gene, copy number 5: RNU6-248P.
- chr8:91,909,738–142,834,940, 702 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:70,056,230–86,216,878, 370 genes, copy number 5 (broad region; genes not listed).
- chr17:81,843,161–81,860,624, 1 gene, copy number 5 (within-gene range 3–5): P4HB.
- chr17:81,862,778–81,947,601, 17 genes, copy number 5 (within-gene range 2–5): AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6, ALYREF, ANAPC11, NPB, PCYT2, SIRT7, MAFG, AC145207.8, MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1.

Autosomal genes at a single copy (total copy number 1): 22,074. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
